Somatic mutation profile of tumor specimen TCGA-G3-A5SL-01A (aliquot TCGA-G3-A5SL-01A-11D-A27I-10) from TCGA case TCGA-G3-A5SL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.3 years (25,671 days).
Specimen TCGA-G3-A5SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beb1b579-8c8c-4215-b39e-d008063c1cf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A5SL-10A (Blood Derived Normal), aliquot TCGA-G3-A5SL-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76366a9b-d84a-4b74-9c92-1157f3a19de2

The open-access MAF lists 149 somatic variants for this specimen: 115 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 21, Frame Shift Del 6, 5'UTR 5, Frame Shift Ins 4, 3'UTR 3, Nonsense Mutation 3, RNA 2, Splice Site 2, Intron 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 66/207 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs730880868, CM032602, COSV62517652; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RDH12 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894476, CM042470, COSV50823501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.3694A>G p.S1232G | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); catalogued as COSV52983221; called by muse, mutect2, varscan2
- ADGRB1 | c.3827T>C p.F1276S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60104166; called by muse, mutect2
- ADORA2A | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as rs201827862, COSV58381116; called by muse, mutect2, varscan2
- ADSS2 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63696506; called by muse, mutect2, varscan2
- AIPL1 | c.995C>G p.T332R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs770159814, COSV51509341, COSV51509546; called by muse, mutect2, varscan2
- AKAP3 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57421708; called by muse, mutect2, varscan2
- AKR7A2 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV52517076; called by muse, mutect2, varscan2
- ANAPC7 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs930175620, COSV71444098; called by muse, mutect2, varscan2
- ANKRD50 | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72386440; called by muse, mutect2, varscan2
- ARID2 | c.3817C>T p.R1273* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV57603720, COSV57615266; called by muse, mutect2, varscan2
- BASP1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100493792, COSV59474401; called by muse, mutect2, varscan2
- BAZ2B | c.2062G>C p.G688R | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV58611827; called by muse, mutect2
- BCL9 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52351440; called by muse, mutect2, varscan2
- BTBD1 | c.951C>A p.Y317* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as COSV55605514; called by muse, mutect2
- C16orf46 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55153810; called by muse, mutect2, varscan2
- CD1C | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63807941; called by muse, mutect2, varscan2
- CEP104 | c.1552A>T p.S518C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV65520223; called by muse, mutect2, varscan2
- CHL1 | c.3065T>C p.I1022T (on ENST00000397491 / NM_001253387.1; = p.I1038T on NM_006614.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1266012181, COSV56609602; called by muse, mutect2, varscan2
- CLCA1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52332264; called by muse, mutect2, varscan2
- CNNM4 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772023576, COSV65662350; called by muse, mutect2, varscan2
- CNTRL | c.6877G>A p.A2293T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53054774; called by muse, mutect2, varscan2
- COL18A1 | c.1513C>T p.R505C (on ENST00000359759 / NM_130444.3; = p.R270C on NM_030582.4) | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs778941505, COSV62708260; called by muse, mutect2, varscan2
- COL1A1 | c.3686T>A p.L1229H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56810410; called by muse, mutect2, varscan2
- COL2A1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.123); catalogued as COSV61535424; called by muse, mutect2, varscan2
- COLGALT1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as COSV53111979; called by muse, mutect2, varscan2
- CPB1 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51577678; called by muse, mutect2, varscan2
- CYP11B2 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 51/501 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV59994347; called by muse, mutect2
- CYP8B1 | c.389A>T p.H130L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV60227894; called by muse, mutect2, varscan2
- DDX42 | c.221+1del p.X74_splice | Splice Site (DEL) | VAF 19/89 reads (21%) | catalogued as COSV63790704; called by mutect2, pindel, varscan2
- DNAH11 | c.8173C>T p.P2725S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV60987179; called by muse, mutect2, varscan2
- DSCAML1 | c.3836G>A p.G1279E (on ENST00000321322; = p.G1219E on NM_020693.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58392768; called by muse, mutect2
- DUSP22 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100739807, COSV60532435; called by muse, mutect2
- EPAS1 | c.2536G>T p.V846L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55391096; called by muse, varscan2
- EPHA5 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1342407694, COSV56680010; called by muse, mutect2, varscan2
- FCRL1 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV63828138; called by muse, mutect2
- FGA | c.1948A>G p.I650V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV57402202; called by muse, mutect2, varscan2
- FRMD4A | c.1543A>C p.N515H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV52738561; called by muse, mutect2, varscan2
- HBE1 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.19); catalogued as COSV53081674; called by muse, mutect2, varscan2
- HGF | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55946417, COSV55946700, COSV55957150; called by muse, mutect2, varscan2
- IL36A | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52084069; called by muse, mutect2, varscan2
- ITGA8 | c.3179C>G p.T1060S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV65237637; called by muse, mutect2, varscan2
- KCNK2 | c.1087C>T p.R363W (on ENST00000444842 / NM_001017425.3; = p.R348W on NM_014217.4) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67211366; called by muse, mutect2, varscan2
- KCNQ3 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.572); catalogued as COSV101196639, COSV66484353; called by muse, mutect2, varscan2
- KIAA1522 | c.1069T>C p.W357R (on ENST00000373480 / NM_001198972.2; = p.W416R on NM_020888.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV53868485; called by muse, mutect2
- KLHL26 | c.1684T>G p.Y562D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56320163; called by muse, varscan2
- LAMA3 | c.4516C>A p.L1506I | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as rs1179634465, COSV58083467; called by muse, mutect2, varscan2
- LGI2 | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV66124320; called by muse, mutect2, varscan2
- LRP5 | c.2642T>G p.L881R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV53725005; called by muse, mutect2, varscan2
- LRP5 | c.4652A>T p.D1551V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV53725014; called by muse, mutect2, varscan2
- MAGEE2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs867972521, COSV64898691; called by muse, mutect2, varscan2
- MAP3K11 | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58419008, COSV58422229; called by muse, mutect2, varscan2
- MFSD14B | c.918G>A p.T306= | Splice Region (SNP) | VAF 24/71 reads (34%) | catalogued as rs772519754, COSV64702288; called by muse, varscan2
- MUC5B | c.7975C>T p.P2659S | Missense Mutation (SNP) | VAF 54/808 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV71590398; called by muse, mutect2
- NFATC4 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs752150894, COSV51613577; called by muse, mutect2, varscan2
- NIPBL | c.4894G>C p.G1632R | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV56969544; called by muse, mutect2
- NOD2 | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1355322844, COSV56055564; called by muse, mutect2, varscan2
- NPBWR1 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV58697879; called by muse, varscan2
- NPR2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as COSV52416117; called by muse, mutect2, varscan2
- NR0B2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54260413; called by muse, mutect2, varscan2
- PCLO | c.11993C>T p.A3998V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV61676028; called by muse, mutect2, varscan2
- PDGFD | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56368215; called by muse, mutect2, varscan2
- PHF10 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV59324824; called by muse, mutect2, varscan2
- PIK3C2G | c.3344T>G p.F1115C (on ENST00000676171; = p.F1074C on NM_004570.5) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1403012337, COSV56838494; called by muse, mutect2, varscan2
- PKHD1 | c.2872G>T p.D958Y | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61898438; called by muse, mutect2, varscan2
- PRKG1 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1202969138, COSV64779678; called by muse, mutect2, varscan2
- PTPA | c.701A>G p.Y234C (on ENST00000337738 / NM_178001.2; = p.Y199C on NM_021131.5) | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61234857; called by muse, mutect2, varscan2
- RAI14 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV54305115; called by muse, mutect2, varscan2
- RASA1 | c.2165A>C p.E722A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV57203687; called by muse, mutect2
- RELN | c.7142A>G p.D2381G | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV59039582; called by muse, mutect2, varscan2
- RTL6 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57980702; called by muse, mutect2, varscan2
- SGPP1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55974963, COSV55976917; called by muse, mutect2, varscan2
- SIRT3 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV66953865; called by muse, mutect2, varscan2
- SLC47A1 | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54504774; called by muse, mutect2, varscan2
- SMG7 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.518); catalogued as COSV61634897; called by muse, mutect2, varscan2
- SPTA1 | c.4206del p.N1403Tfs*16 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | catalogued as COSV63751130; called by mutect2, pindel, varscan2
- SRR | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56787561; called by muse, mutect2, varscan2
- TAGLN2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV57424003; called by muse, mutect2, varscan2
- TINF2 | c.1276T>G p.C426G | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.194); catalogued as COSV57468057, COSV57471023; called by muse, mutect2, varscan2
- TLR4 | c.2256G>C p.E752D (on ENST00000355622 / NM_138554.5; = p.E712D on NM_003266.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.259); catalogued as COSV62924513; called by muse, mutect2
- TNXB | c.6264G>T p.K2088N (on ENST00000647633; = p.K1841N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64490797; called by muse, mutect2
- TNXB | c.5200C>A p.P1734T (on ENST00000647633; = p.P1487T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV64490810; called by muse, mutect2, varscan2
- TP73 | c.1695C>A p.N565K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60706221, COSV60706918; called by muse, mutect2
- UNC80 | c.7544A>G p.Q2515R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.922); catalogued as COSV55909384; called by muse, mutect2, varscan2
- UQCRB | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs376775585; called by muse, mutect2
- UTP6 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55572601, COSV55576299; called by muse, mutect2
- VIRMA | c.3263A>G p.N1088S | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52592448; called by muse, mutect2, varscan2
- VIRMA | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 80/112 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52583004; called by muse, mutect2, varscan2
- VSIG10 | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV63654676; called by muse, varscan2
- WDR17 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748882959, COSV54567452; called by mutect2, varscan2
- XPO4 | c.3151C>G p.R1051G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV55009251, COSV55014607; called by muse, mutect2, varscan2
- ZC3H12C | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV53713711; called by muse, mutect2, varscan2
- ZEB1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV58057079; called by muse, mutect2, varscan2
- ZFYVE26 | c.1934T>A p.M645K | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV61334462; called by muse, mutect2, varscan2
- ZNF17 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV56922760; called by muse, mutect2
- ZNF471 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57294137; called by muse, mutect2, varscan2
- ZNF816 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54413048; called by muse, mutect2, varscan2
- BPIFC | c.1479dup p.L494Sfs*35 | Frame Shift Ins (INS) | VAF 20/191 reads (10%) | called by mutect2, pindel, varscan2
- C7orf50 | c.448_453del p.G150_L151del | In Frame Del (DEL) | VAF 9/123 reads (7%) | called by mutect2, pindel
- CHD9 | c.2546_2547del p.D849Afs*6 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel
- CIITA | c.3270dup p.Q1091Afs*61 | Frame Shift Ins (INS) | VAF 41/128 reads (32%) | called by mutect2, pindel, varscan2
- DNAAF1 | c.1790del p.N597Tfs*50 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- FOXD4L5 | c.968C>G p.S323C | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); called by mutect2, varscan2
- HOOK2 | c.45+1del p.X15_splice | Splice Site (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- KRT72 | c.1359del p.S453Rfs*189 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- KRTAP9-6 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- KRTAP9-7 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MPI | c.65dup p.S23Ffs*13 | Frame Shift Ins (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- NELFE | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- NT5C3A | c.644_648del p.Y215Sfs*13 (on ENST00000610140 / NM_001374335.1; = p.Y181Sfs*13 on NM_016489.13) | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- SERTAD4 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2
- SIMC1 | c.1307A>G p.Y436C (on ENST00000443967 / NM_001308196.1; = p.Y455C on NM_001308195.2) | Missense Mutation (SNP) | VAF 240/634 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.55); called by muse, varscan2
- TTN | c.19690del p.Q6564Sfs*14 (on ENST00000591111; = p.Q5637Sfs*14 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- ANGPTL3 | c.30T>A p.I10= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV52024379; called by muse, mutect2, varscan2
- APLP1 | c.921C>T p.H307= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs751432524, COSV55707553; called by muse, mutect2, varscan2
- BRINP2 | c.789G>A p.L263= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as COSV64180332; called by muse, mutect2, varscan2
- DELE1 | c.916T>C p.L306= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs754377097, COSV52006969; called by muse, mutect2, varscan2
- FARP2 | c.2520A>G p.K840= | Silent (SNP) | VAF 70/221 reads (32%) | catalogued as COSV50885429; called by muse, mutect2, varscan2
- FASN | c.5598G>A p.K1866= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV60762505; called by muse, mutect2, varscan2
- GFAP | c.918G>A p.L306= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1232753133, COSV53654321; called by muse, mutect2, varscan2
- ITPRID1 | c.2421C>A p.I807= | Silent (SNP) | VAF 92/179 reads (51%) | catalogued as COSV60084860; called by muse, mutect2, varscan2
- MAP3K8 | c.951C>A p.L317= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs746280858, COSV53922196; called by muse, mutect2, varscan2
- MNDA | c.348C>T p.P116= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as COSV63740784, COSV63742305; called by muse, mutect2, varscan2
- NUP98 | c.411T>A p.S137= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV61428976, COSV61440005; called by muse, mutect2, varscan2
- PCDHB10 | c.522C>T p.P174= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV53384899; called by muse, mutect2, varscan2
- PEX5L | c.654A>G p.P218= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV55860088; called by muse, mutect2, varscan2
- PLA2G4A | c.2022A>G p.P674= | Silent (SNP) | VAF 74/153 reads (48%) | catalogued as COSV66552958; called by muse, mutect2, varscan2
- PRDM15 | c.3153C>T p.T1051= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV54160890; called by muse, mutect2, varscan2
- PTPRA | c.1089G>A p.G363= | Silent (SNP) | VAF 72/200 reads (36%) | catalogued as rs1568702000, COSV53790009; called by muse, mutect2, varscan2
- RBMS3 | c.1275A>G p.E425= (on ENST00000383767 / NM_001003793.3; = p.E409= on NM_014483.3) | Silent (SNP) | VAF 78/186 reads (42%) | catalogued as COSV56170497; called by muse, mutect2, varscan2
- SBF1 | c.5304T>A p.A1768= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as COSV53299852; called by muse, mutect2, varscan2
- SLC38A3 | c.75C>T p.V25= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs767194548, COSV68844214; called by muse, mutect2, varscan2
- SLC4A3 | c.2988C>A p.V996= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV56098391; called by muse, mutect2, varscan2
- TMEM67 | c.2409A>G p.E803= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV60045496; called by muse, mutect2
- AP1S2 | c.427-5597G>C | Intron (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- CARD10 | c.910-382C>T | Intron (SNP) | VAF 13/298 reads (4%) | catalogued as COSV99324565; called by muse, mutect2
- FGG | c.-10C>G | 5'UTR (SNP) | VAF 43/142 reads (30%) | catalogued as COSV100271669; called by muse, mutect2, varscan2
- IGLV1-50 | c.-1C>T | 5'UTR (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2
- KPRP | c.*403T>G | 3'UTR (SNP) | VAF 14/209 reads (7%) | catalogued as COSV100908656; called by muse, mutect2
- METTL16 | n.1152A>T | RNA (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- MIR524 | n.76T>C | RNA (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- MPZL3 | c.*21G>A | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- OSBPL2 | c.-27G>C | 5'UTR (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100569111; called by muse, mutect2, varscan2
- OSBPL2 | c.-26G>T | 5'UTR (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100569112; called by muse, mutect2, varscan2
- PAAF1 | c.-4C>A | 5'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100142289; called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458539 C>T | 5'Flank (SNP) | VAF 11/59 reads (19%) | catalogued as COSV66911351; called by muse, mutect2
- TXNDC17 | c.*12G>C | 3'UTR (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99854480; called by muse, mutect2, varscan2
